Somatic mutation profile of tumor specimen C3L-02463-02 (aliquot CPT0126160010_1) from CPTAC case C3L-02463, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.8 years (23,313 days).
Specimen C3L-02463-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9c7fb84-f220-4db3-a6a3-ea4119aa8beb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02463-31 (Blood Derived Normal), aliquot CPT0124290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4b9fc7b-2295-4aa6-81c6-1043223d772d

The open-access MAF lists 61 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Frame Shift Del 4, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 103/508 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- SMAD4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 117/474 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61684095, COSV61696676; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 200/917 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs144077662, COSV54450723; called by muse, mutect2, varscan2
- ANKRD13B | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV61470366; called by muse, mutect2, varscan2
- ANKRD2 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV53967325; called by muse, mutect2, varscan2
- ASXL3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs931090804; called by muse, mutect2, varscan2
- ATP1A2 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 110/700 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV63401929; called by muse, mutect2, varscan2
- CCT3 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs368091711, COSV104403468; called by muse, mutect2, varscan2
- EEFSEC | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 66/360 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1009397010; called by muse, mutect2, varscan2
- GNAI1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204209552, COSV63522708; called by muse, mutect2, varscan2
- HCN1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV57491706, COSV57502530; called by muse, mutect2, varscan2
- HRNR | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 73/388 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs1267008841; called by muse, mutect2, varscan2
- HSP90AB1 | c.1655A>T p.K552M | Missense Mutation (SNP) | VAF 107/586 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs756933263, COSV100806874; called by muse, mutect2, varscan2
- KCNA1 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV66837485; called by muse, mutect2, varscan2
- LHX8 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 136/642 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53955118; called by muse, mutect2, varscan2
- LY75 | c.4729G>A p.D1577N | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV55106322; called by muse, mutect2, varscan2
- MACF1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 48/271 reads (18%) | catalogued as COSV57103368; called by muse, mutect2, varscan2
- MEGF10 | c.744del p.H248Qfs*88 | Frame Shift Del (DEL) | VAF 55/381 reads (14%) | catalogued as COSV99175049; called by mutect2, pindel, varscan2
- PCDHB4 | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 253/1345 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV52024048; called by muse, mutect2, varscan2
- PLEKHG2 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs374823888; called by muse, mutect2, varscan2
- REG3G | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV99709703; called by muse, mutect2, varscan2
- SALL3 | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs146109999; called by muse, mutect2, varscan2
- ST6GAL2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 38/192 reads (20%) | PolyPhen benign (0.001); catalogued as COSV100867644; called by muse, mutect2, varscan2
- UNC5B | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 80/568 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779677077, COSV58976573; called by muse, mutect2, varscan2
- VAX1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 83/432 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778224173; called by muse, mutect2, varscan2
- WTAP | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as COSV61610182; called by muse, mutect2, varscan2
- AICDA | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 150/757 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPB1 | c.1039_1040del p.L347Cfs*4 | Frame Shift Del (DEL) | VAF 45/344 reads (13%) | called by mutect2, pindel, varscan2
- FOLH1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 93/583 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FRY | c.6572T>A p.L2191H | Missense Mutation (SNP) | VAF 77/432 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV5-37 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 62/678 reads (9%) | called by muse, mutect2
- KCTD3 | c.1370C>G p.S457C | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAYN | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 110/647 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- PLXNB2 | c.3166del p.L1056Cfs*17 | Frame Shift Del (DEL) | VAF 94/516 reads (18%) | called by mutect2, pindel, varscan2
- PUS7L | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RAPGEF6 | c.3579G>C p.R1193S | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RASGRF2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- RMDN1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RNF43 | c.1370del p.Y457Sfs*45 | Frame Shift Del (DEL) | VAF 41/208 reads (20%) | called by mutect2, pindel, varscan2
- SOX5 | c.1786G>C p.A596P | Missense Mutation (SNP) | VAF 95/509 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SYTL4 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TET2 | c.221dup p.S75Efs*3 | Frame Shift Ins (INS) | VAF 95/572 reads (17%) | called by mutect2, pindel, varscan2
- TONSL | c.1681T>C p.C561R | Missense Mutation (SNP) | VAF 93/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53TG5 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 84/481 reads (17%) | called by muse, mutect2, varscan2
- TTC29 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 120/684 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF729 | c.2024A>C p.K675T | Missense Mutation (SNP) | VAF 96/568 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, varscan2
- ZNF781 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ADGRB1 | c.1845G>C p.R615= | Silent (SNP) | VAF 85/469 reads (18%) | catalogued as rs754733336; called by muse, mutect2, varscan2
- HTR3E | c.1122C>T p.L374= (on ENST00000415389 / NM_001256613.1; = p.L389= on NM_182589.2) | Silent (SNP) | VAF 82/307 reads (27%) | called by muse, mutect2, varscan2
- HYI | c.240C>T p.P80= | Silent (SNP) | VAF 53/309 reads (17%) | called by muse, mutect2, varscan2
- L2HGDH | c.981T>C p.P327= | Silent (SNP) | VAF 85/433 reads (20%) | called by muse, mutect2, varscan2
- LIMS2 | c.912G>A p.V304= (on ENST00000355119 / NM_001161403.3; = p.V328= on NM_017980.4) | Silent (SNP) | VAF 56/296 reads (19%) | catalogued as rs757061758; called by muse, mutect2, varscan2
- NT5DC2 | c.198C>T p.D66= | Silent (SNP) | VAF 102/657 reads (16%) | catalogued as rs762216017, COSV58734597; called by muse, mutect2, varscan2
- OBSCN | c.11640G>A p.S3880= | Silent (SNP) | VAF 133/544 reads (24%) | catalogued as rs549657012; called by muse, mutect2, varscan2
- PICALM | c.1737A>G p.Q579= | Silent (SNP) | VAF 63/419 reads (15%) | called by muse, mutect2, varscan2
- REG3G | c.9T>A p.P3= | Silent (SNP) | VAF 56/333 reads (17%) | called by muse, mutect2, varscan2
- RIMS2 | c.1512C>T p.G504= (on ENST00000666250 / NM_001348490.2; = p.G312= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 72/596 reads (12%) | catalogued as rs758569920, COSV51656297; called by muse, mutect2, varscan2
- SCPEP1 | c.828C>T p.S276= | Silent (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- A2M | c.-69G>A | 5'UTR (SNP) | VAF 21/637 reads (3%) | called by muse, mutect2
- WDR20 | chr14:102224654 G>A | 3'Flank (SNP) | VAF 68/441 reads (15%) | called by muse, mutect2, varscan2
